Gene-level copy-number profile of tumor specimen CDDP-ABJZ-TTP1-A from CDDP_EAGLE case CDDP-ABJZ, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 64 years.
Specimen CDDP-ABJZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 731e6cf2-5024-4e63-ae16-fbac1c541ad3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ABJZ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/79581b57-eab3-4b49-a520-cee2c6cfd158

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 1,410; copy number 2: 11,092; copy number 3: 24,638; copy number 4: 14,466; copy number 5: 1,452; copy number 6: 4,147; copy number 7: 1,021; copy number 8: 71; copy number 10: 23; copy number 12: 66; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,355,517–7,509,311, 10 genes: ZNF705G, DEFB108C, DEFB4B, HSPD1P3, DEFB103B, SPAG11B, DEFB104B, DEFB106B, DEFB105B, DEFB107B.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,182 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:80,092,103–86,156,943, 73 genes, copy number 7–8 (broad region; genes not listed).
- chr1:143,419,625–153,348,841, 409 genes, copy number 7 (broad region; genes not listed).
- chr1:154,220,179–162,787,405, 380 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr5:34,158,121–40,269,719, 96 genes, copy number 7–10 (broad region; genes not listed).
- chr5:43,192,071–45,098,647, 32 genes, copy number 7: NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1.
- chr13:87,672,615–87,696,272, 1 gene, copy number 15: SLITRK5.
- chr14:18,333,726–18,650,966, 17 genes, copy number 8: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11.
- chr14:27,258,717–37,172,606, 166 genes, copy number 7–12 (within-gene range 2–12) (broad region; genes not listed).
- chr15:30,098,826–30,179,943, 8 genes, copy number 7: DNM1P28, ULK4P3, U8, GOLGA8T, RN7SL469P, DNM1P30, AC120045.2, AC120045.1.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
